Somatic mutation profile of tumor specimen 0DJTFV from CCDI case PBBXHT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.4 years (1,589 days).
Specimen 0DJTFV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dd2072f-d0ba-4f57-a94b-aabffdd8f69b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJTG1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf489515-be84-43cf-bb37-766ae3329fb6

The open-access MAF lists 45 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Intron 4, 5'UTR 2, 3'UTR 1, Nonsense Mutation 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 468/1143 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADGRV1 | c.15787G>A p.G5263S | Missense Mutation (SNP) | VAF 470/1136 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs372897733; called by muse, mutect2, varscan2
- C2CD2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 416/1028 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200093070, COSV61599423; called by muse, mutect2, varscan2
- CCDC116 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 168/359 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.43); catalogued as rs566751888, COSV99488777; called by muse, mutect2, varscan2
- DICER1 | c.5439G>C p.E1813D | Missense Mutation (SNP) | VAF 524/1086 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as CM160049, COSV58615264, COSV58615771; called by muse, mutect2, varscan2
- H2BC9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 254/618 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV55099863, COSV55100002; called by muse, mutect2, varscan2
- KMT2B | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 151/314 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.476); catalogued as rs1198219194; called by muse, mutect2, varscan2
- KPRP | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 176/443 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); catalogued as COSV64222167; called by muse, mutect2
- LOXHD1 | c.4411A>G p.I1471V | Missense Mutation (SNP) | VAF 458/1056 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as rs1177665455; called by muse, mutect2, varscan2
- METTL11B | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 364/831 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1309437371, COSV63029663, COSV63030217; called by muse, mutect2, varscan2
- RASA1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 264/590 reads (45%) | catalogued as CM1311700, COSV57195137; called by muse, mutect2, varscan2
- SLC4A1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 262/567 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1427615024; called by muse, mutect2, varscan2
- WFDC13 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 241/575 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57913778; called by muse, mutect2, varscan2
- ZNF398 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 289/820 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100247095; called by muse, mutect2, varscan2
- ADAMTS9 | c.2539C>A p.Q847K | Missense Mutation (SNP) | VAF 299/729 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by mutect2, varscan2
- ALOX5 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 378/766 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.7816A>T p.S2606C | Missense Mutation (SNP) | VAF 184/406 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CMAS | c.1180T>A p.C394S | Missense Mutation (SNP) | VAF 412/980 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CNTNAP4 | c.3542C>A p.A1181E | Missense Mutation (SNP) | VAF 298/676 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CSRNP3 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 592/1398 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN3 | c.2519C>A p.A840E | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- NEGR1 | c.223T>A p.S75T | Missense Mutation (SNP) | VAF 369/937 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NEU1 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 233/538 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR1L8 | c.451T>A p.S151T | Missense Mutation (SNP) | VAF 409/918 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- ROBO2 | c.934G>C p.A312P | Missense Mutation (SNP) | VAF 116/880 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SRPRA | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 340/782 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- WDR6 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 227/526 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 22/648 reads (3%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- ALPG | c.468G>A p.K156= | Silent (SNP) | VAF 279/781 reads (36%) | called by muse, mutect2, varscan2
- ARHGEF39 | c.612C>T p.D204= | Silent (SNP) | VAF 376/834 reads (45%) | catalogued as rs989137766; called by muse, mutect2, varscan2
- EPB41L4B | c.1248T>A p.R416= | Silent (SNP) | VAF 127/851 reads (15%) | called by muse, mutect2, varscan2
- GRIN2B | c.246C>T p.I82= | Silent (SNP) | VAF 45/663 reads (7%) | called by muse, mutect2
- ITGA1 | c.3255G>A p.S1085= | Silent (SNP) | VAF 488/1074 reads (45%) | catalogued as rs753899066; called by muse, mutect2, varscan2
- LYST | c.8490T>C p.P2830= | Silent (SNP) | VAF 407/1517 reads (27%) | called by muse, mutect2, varscan2
- NBPF12 | c.1138T>C p.L380= | Silent (SNP) | VAF 23/300 reads (8%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1257C>T p.S419= | Silent (SNP) | VAF 92/1026 reads (9%) | catalogued as COSV65325550; called by muse, mutect2
- PLIN1 | c.870C>G p.A290= | Silent (SNP) | VAF 259/665 reads (39%) | catalogued as rs775295801; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 20/400 reads (5%) | called by muse, mutect2
- GLRA3 | c.*3135del | 3'UTR (DEL) | VAF 67/142 reads (47%) | catalogued as rs569067653; called by mutect2, varscan2
- LHFPL2 | c.-14C>A | 5'UTR (SNP) | VAF 60/303 reads (20%) | called by muse, mutect2, varscan2
- MSH4 | c.-54T>A | 5'UTR (SNP) | VAF 63/135 reads (47%) | called by muse, mutect2, varscan2
- PLCH2 | c.2959+536C>T | Intron (SNP) | VAF 53/119 reads (45%) | catalogued as rs763489308, COSV53949870; called by muse, mutect2, varscan2
- POU3F4 | chrX:83508232 G>C | 5'Flank (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- SAT1 | c.119-38G>T | Intron (SNP) | VAF 34/490 reads (7%) | called by muse, mutect2
- SECISBP2L | c.1036-89G>T | Intron (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
